Somatic mutation profile of tumor specimen TCGA-63-A5ML-01A (aliquot TCGA-63-A5ML-01A-31D-A27K-08) from TCGA case TCGA-63-A5ML, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d038bc8-1977-4ef7-8006-f98d3b322195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5ML-10A (Blood Derived Normal), aliquot TCGA-63-A5ML-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47b46527-5854-4404-a566-708aa1ac4faf

The open-access MAF lists 274 somatic variants for this specimen: 210 protein-altering or splice-affecting, 57 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 57, Nonsense Mutation 15, Frame Shift Del 6, Splice Site 5, Frame Shift Ins 4, RNA 4, Translation Start Site 2, Intron 2, In Frame Del 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 42/105 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV99714766; called by muse, mutect2, varscan2
- ABCC11 | c.3755A>C p.E1252A | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100751240; called by muse, mutect2
- ABCC12 | c.2422A>T p.S808C | Missense Mutation (SNP) | VAF 95/133 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV100253412; called by muse, mutect2, varscan2
- AC126283.2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.965); catalogued as COSV101144811, COSV67099327; called by muse, mutect2, varscan2
- ACACA | c.3433A>G p.I1145V | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1307135107; called by muse, mutect2, varscan2
- ACP3 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100313634; called by muse, mutect2, varscan2
- ACSF2 | c.1837C>G p.L613V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99364436; called by muse, mutect2, varscan2
- ACTRT1 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 98/116 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749467254, COSV64419166, COSV64419302; called by muse, mutect2, varscan2
- ADAM29 | c.594G>C p.R198S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV100822304; called by muse, mutect2, varscan2
- ADAMTS12 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711785; called by muse, mutect2, varscan2
- ADAMTS16 | c.3482C>G p.S1161* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99943470; called by muse, mutect2, varscan2
- ADGRB1 | c.1562T>A p.V521E | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs1278404059, COSV100030565; called by muse, mutect2, varscan2
- ADNP | c.2609A>C p.K870T | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.514); catalogued as COSV100823898; called by muse, mutect2, varscan2
- ALDOB | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 137/170 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570143313, COSV100878950; called by muse, mutect2, varscan2
- ALKBH4 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV99479600; called by muse, mutect2, varscan2
- ALLC | c.1065del p.D355Efs*4 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV52993134; called by mutect2, pindel, varscan2
- AMER3 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as rs757113341, COSV100367002; called by muse, mutect2, varscan2
- ANAPC15 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99921511; called by muse, mutect2, varscan2
- ANK2 | c.10924C>T p.R3642* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV100004730; called by muse, mutect2, varscan2
- ANKRD30A | c.1667C>A p.S556Y (on ENST00000611781; = p.S500Y on NM_052997.2) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100653252, COSV64608220; called by muse, mutect2, varscan2
- ANKRD33 | c.356G>T p.R119L (on ENST00000340970 / NM_001304459.2; = p.R244L on NM_182608.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100001588; called by muse, mutect2, varscan2
- ANO3 | c.2426T>C p.I809T | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99886500; called by muse, mutect2, varscan2
- ANXA11 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV55416807; called by muse, mutect2, varscan2
- ANXA11 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99627639; called by muse, mutect2, varscan2
- AP3D1 | c.1857A>C p.E619D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100643117; called by muse, mutect2, varscan2
- APLP1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768272777, COSV55707182; called by muse, mutect2, varscan2
- ASCC3 | c.6520G>C p.D2174H | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100976358, COSV100977058; called by muse, mutect2, varscan2
- ASCC3 | c.834A>T p.E278D | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV100226486; called by muse, mutect2, varscan2
- ATP5MG | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100329290; called by muse, mutect2, varscan2
- B3GNT6 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0.059); catalogued as COSV100845821; called by muse, mutect2, varscan2
- BIRC7 | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99417064; called by muse, mutect2, varscan2
- BMPR2 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 58/75 reads (77%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV101001775; called by muse, mutect2, varscan2
- BOD1L1 | c.4321G>T p.D1441Y | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV50012351; called by muse, mutect2, varscan2
- BRINP3 | c.428-1G>T p.X143_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100819609; called by mutect2, varscan2
- C8orf34 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100448245, COSV61385316; called by muse, mutect2, varscan2
- C8orf34 | c.1128G>T p.M376I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV57401898; called by muse, mutect2, varscan2
- CASP1 | c.458A>T p.Y153F (on ENST00000436863 / NM_033292.4; = p.Y132F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100782880; called by muse, mutect2, varscan2
- CCDC158 | c.3017A>T p.N1006I | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101187426; called by muse, mutect2, varscan2
- CCT8L2 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100743244; called by muse, mutect2, varscan2
- CDH10 | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.029); catalogued as COSV100053487; called by muse, mutect2, varscan2
- CDH13 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs1316238102, COSV99232322; called by muse, mutect2, varscan2
- CDON | c.2298G>T p.W766C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702159; called by muse, mutect2, varscan2
- CEBPZ | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV99135862; called by muse, mutect2, varscan2
- CETN3 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 43/63 reads (68%) | catalogued as COSV51617451; called by muse, mutect2, varscan2
- CFAP61 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99846988; called by muse, mutect2, varscan2
- CHAF1A | c.2615A>T p.K872M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100011562; called by muse, mutect2, varscan2
- CHD7 | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV101418571; called by muse, mutect2, varscan2
- CLDN18 | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99481071; called by muse, mutect2, varscan2
- CNTNAP2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV62163155; called by muse, mutect2, varscan2
- COMP | c.2218C>A p.R740S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99721394; called by muse, mutect2, varscan2
- CPA3 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99936570; called by muse, mutect2, varscan2
- CSMD3 | c.6611A>T p.D2204V (on ENST00000297405 / NM_001363185.1; = p.D2100V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851265; called by muse, mutect2, varscan2
- DAAM2 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV99227518; called by muse, mutect2, varscan2
- DCAF8 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV100470976; called by muse, mutect2, varscan2
- DDX3Y | c.741A>C p.E247D | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs775130718, COSV100267618; called by muse, mutect2, varscan2
- DMXL2 | c.7456G>A p.E2486K | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99198913; called by muse, mutect2, varscan2
- DNAH11 | c.11018G>A p.R3673K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100181389, COSV60975919; called by muse, mutect2, varscan2
- DNHD1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 116/166 reads (70%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99601161; called by muse, mutect2, varscan2
- DOCK5 | c.5162G>T p.R1721I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV99378305; called by muse, mutect2
- DPY19L4 | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as COSV101363548; called by muse, mutect2, varscan2
- DSP | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV101131875; called by muse, mutect2
- DYM | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV99494424; called by muse, mutect2, varscan2
- ENPP2 | c.2540C>A p.P847Q (on ENST00000075322 / NM_001040092.3; = p.P899Q on NM_006209.5) | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99309598; called by muse, mutect2, varscan2
- EPHA5 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56653813, COSV56682709; called by muse, mutect2, varscan2
- EPHB1 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.799); catalogued as COSV101214743; called by muse, mutect2, varscan2
- ERBB4 | c.1686G>T p.M562I | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99635683; called by muse, mutect2, varscan2
- EXPH5 | c.5302A>C p.S1768R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.038); catalogued as COSV99762389; called by muse, mutect2, varscan2
- FAM135B | c.3809A>T p.K1270I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428571; called by muse, mutect2, varscan2
- FAM210A | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100452556; called by muse, mutect2, varscan2
- FAM47A | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100650126, COSV60494217; called by muse, mutect2
- FGA | c.1891+2T>C p.X631_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as rs1339628244, COSV100120844; called by muse, mutect2
- FITM1 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99246558; called by muse, mutect2, varscan2
- FMN2 | c.4364T>A p.L1455Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100147754; called by muse, mutect2, varscan2
- GIPC2 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 78/105 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100883359; called by muse, mutect2, varscan2
- GOLIM4 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100463624; called by muse, mutect2
- GPR37 | c.359G>C p.W120S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100391217; called by muse, mutect2, varscan2
- GPT2 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413123; called by muse, mutect2, varscan2
- GRIA1 | c.1857G>A p.W619* | Nonsense Mutation (SNP) | VAF 37/47 reads (79%) | catalogued as COSV99602879; called by muse, mutect2, varscan2
- GTSE1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765658379, COSV101483267, COSV71889355, COSV71889681; called by muse, mutect2, varscan2
- HEATR3 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV99590162; called by muse, mutect2, varscan2
- HOXC11 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV99678574; called by muse, mutect2, varscan2
- HSPA1L | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100989466; called by muse, mutect2, varscan2
- IFNL3 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV101308034; called by muse, mutect2, varscan2
- INTS6L | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100878355; called by muse, mutect2, varscan2
- IQCN | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV101149109; called by muse, mutect2, varscan2
- ITSN2 | c.3718G>T p.A1240S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100744284; called by muse, mutect2
- KCNQ2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV60434765; called by muse, mutect2, varscan2
- KHDRBS2 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99838544; called by muse, mutect2, varscan2
- KIRREL1 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs148421111, COSV63289462; called by muse, mutect2, varscan2
- KPNA4 | c.1396C>G p.Q466E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100515402; called by muse, mutect2, varscan2
- KRT15 | c.726_728del p.K242del | In Frame Del (DEL) | VAF 50/128 reads (39%) | catalogued as rs1387332378; called by pindel, varscan2
- LCOR | c.367G>T p.G123* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100603980; called by muse, mutect2, varscan2
- LGI1 | c.1562C>A p.A521E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV101004500; called by muse, mutect2, varscan2
- LIG4 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800120; called by muse, mutect2, varscan2
- LMX1A | c.1092A>T p.R364S | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.73); catalogued as COSV99673405; called by muse, mutect2, varscan2
- LRBA | c.6154A>T p.N2052Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100842168; called by muse, mutect2, varscan2
- LRRK2 | c.5459A>G p.E1820G | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100111415; called by muse, mutect2, varscan2
- MAGEC1 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 141/171 reads (82%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV99596797; called by muse, mutect2, varscan2
- MAGED1 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV100431911; called by muse, mutect2, varscan2
- MAU2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as rs774506990, COSV53233951; called by muse, mutect2, varscan2
- MEX3B | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as rs1400186954, COSV100314264; called by muse, mutect2
- MIDN | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99960463; called by muse, mutect2, varscan2
- MORC2 | c.1904C>G p.P635R (on ENST00000397641 / NM_001303256.3; = p.P573R on NM_014941.3) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99309991, COSV99310602; called by muse, mutect2, varscan2
- MS4A3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as COSV53937409; called by muse, mutect2, varscan2
- MTDH | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV100292854; called by muse, mutect2, varscan2
- MYEF2 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as rs867729468, COSV99982279; called by muse, mutect2, varscan2
- MYH4 | c.4384C>A p.Q1462K | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV99702526; called by muse, mutect2, varscan2
- MYO15A | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99234859; called by muse, mutect2, varscan2
- MYO3A | c.2737C>A p.R913S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs550530253, COSV56324161, COSV99781993; called by muse, mutect2, varscan2
- N4BP2L1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as rs1278035446, COSV100583134; called by muse, mutect2, varscan2
- NCAM2 | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.661); catalogued as COSV99525896; called by muse, mutect2, varscan2
- NCAPD2 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1230379033, COSV100217515; called by muse, mutect2, varscan2
- NDST3 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99632219; called by muse, mutect2, varscan2
- NDUFA9 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs1227948776, COSV99866234; called by muse, mutect2, varscan2
- NFAT5 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100591345; called by muse, mutect2, varscan2
- NLRP2 | c.2659T>C p.F887L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99672727; called by muse, mutect2, varscan2
- OAS3 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747682756, COSV99966643; called by muse, mutect2, varscan2
- OPA3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.114); catalogued as COSV99841195; called by muse, mutect2, varscan2
- OR1M1 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV70037118; called by muse, mutect2, varscan2
- OR1S2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100224397; called by muse, mutect2, varscan2
- OR2T2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs757608530, COSV100737702, COSV61617603, COSV61618057; called by muse, mutect2, varscan2
- OR2T2 | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV100737824; called by muse, mutect2, varscan2
- OR4N5 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 156/217 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100374268, COSV61320782; called by muse, mutect2, varscan2
- OR51G1 | c.620G>C p.C207S | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV100429472; called by muse, mutect2, varscan2
- OR5AC2 | c.781T>A p.Y261N | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684541, COSV62279694; called by muse, mutect2, varscan2
- OR5J2 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100399311; called by muse, mutect2, varscan2
- OR7G2 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.094); catalogued as COSV100560605; called by muse, mutect2, varscan2
- OSBPL8 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs771344329, COSV99675746; called by muse, mutect2, varscan2
- PAK2 | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 71/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100506425; called by muse, mutect2, varscan2
- PCDH10 | c.1583T>A p.L528Q | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV99074920, COSV99994757; called by muse, mutect2, varscan2
- PCDH11X | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100016134, COSV53513454; called by muse, mutect2, varscan2
- PCDH15 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100229152, COSV57372533; called by muse, mutect2, varscan2
- PCDHB11 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs782535816, COSV61310815; called by muse, mutect2, varscan2
- PCDHGA10 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1162432290, COSV99549114; called by muse, mutect2, varscan2
- PDE6B | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99728588; called by muse, mutect2, varscan2
- PLCH1 | c.1190G>A p.S397N (on ENST00000340059 / NM_001130960.2; = p.S409N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV100398524, COSV58212264; called by muse, mutect2, varscan2
- PLXNA4 | c.1296G>T p.M432I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100327901; called by muse, mutect2, varscan2
- POMGNT1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | PolyPhen probably damaging (0.979); catalogued as rs1164265990, COSV100915853, COSV64340898; called by muse, mutect2
- POU6F2 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs192309744, COSV101302775, COSV101302905; called by muse, mutect2, varscan2
- PPP1R12A | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99700987; called by muse, mutect2
- PRKCB | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV100333208; called by muse, mutect2, varscan2
- PROKR2 | c.458+1G>C p.X153_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99450747; called by muse, mutect2
- PTH2R | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 166/226 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99783017; called by muse, mutect2, varscan2
- PZP | c.4292A>G p.Q1431R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV99739992; called by muse, mutect2, varscan2
- RABGGTB | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 83/127 reads (65%) | SIFT tolerated (0.9); PolyPhen benign (0.246); catalogued as COSV54212382, COSV99592798; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99624678; called by muse, mutect2, varscan2
- RBP3 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs782314171; called by muse, mutect2, varscan2
- REG3G | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV99709783; called by muse, mutect2, varscan2
- RP1 | c.1781A>T p.N594I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99609181; called by muse, mutect2
- RUBCN | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1027777658, COSV99583331, COSV99585317; called by muse, mutect2
- RUNX1T1 | c.1798G>A p.E600K (on ENST00000265814 / NM_001198628.1; = p.E573K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs754078185, COSV56165031; called by muse, mutect2, varscan2
- SALL1 | c.2535C>A p.D845E | Missense Mutation (SNP) | VAF 88/122 reads (72%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.695); catalogued as COSV51754684, COSV99192450; called by muse, mutect2, varscan2
- SEPTIN10 | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100454409; called by muse, mutect2, varscan2
- SGMS2 | c.1097G>C p.*366Sext*14 | Nonstop Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV62989682; called by muse, mutect2, varscan2
- SHPRH | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs750369986, COSV51604239, COSV99261131; called by muse, mutect2, varscan2
- SLC10A6 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99907427; called by muse, mutect2, varscan2
- SLC26A11 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100755491; called by muse, mutect2, varscan2
- SLC5A4 | c.1094C>A p.A365E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99832238; called by muse, mutect2
- SLCO5A1 | c.1289G>T p.S430I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99481307; called by muse, mutect2, varscan2
- SLITRK4 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as COSV62024129; called by muse, mutect2, varscan2
- SNX25 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253624; called by muse, mutect2, varscan2
- SPHKAP | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100764648, COSV60873840; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2578C>A p.Q860K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100562366; called by muse, mutect2, varscan2
- STRIP2 | c.235A>C p.N79H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV99974257; called by muse, mutect2, varscan2
- TAOK2 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99665734; called by muse, mutect2, varscan2
- TASOR2 | c.5606C>T p.S1869L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs376540333; called by muse, mutect2, varscan2
- TBC1D25 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV100952257, COSV65124143; called by mutect2, varscan2
- TEX15 | c.6154A>T p.I2052F (on ENST00000256246; = p.I2435F on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV99822347; called by muse, mutect2, varscan2
- TFAP2D | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99148443; called by muse, mutect2, varscan2
- THRB | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as CM984642, COSV99769849; called by muse, mutect2, varscan2
- THSD7A | c.3860G>T p.C1287F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101439811; called by muse, mutect2, varscan2
- TMEM225 | c.294A>G p.I98M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.329); catalogued as COSV100902911; called by muse, mutect2, varscan2
- TNR | c.2777C>G p.A926G | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.78); catalogued as COSV99692115, COSV99692168; called by muse, mutect2, varscan2
- TP53 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 67/174 reads (39%) | catalogued as COSV52677652, COSV52734727, COSV52787469, COSV53371041; called by muse, mutect2, varscan2
- TPTE2 | c.1541C>T p.A514V (on ENST00000400230 / NM_199254.2; = p.A437V on NM_130785.3) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99691253; called by muse, mutect2, varscan2
- TRDN | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs760549842, COSV100523656, COSV62116193; called by muse, mutect2, varscan2
- TTN | c.74212C>G p.L24738V (on ENST00000591111; = p.L17314V on NM_003319.4) | Missense Mutation (SNP) | VAF 127/172 reads (74%) | PolyPhen benign (0.001); catalogued as COSV100634907; called by muse, mutect2, varscan2
- TUBB8 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.029); catalogued as rs1397428604, COSV100226226; called by muse, mutect2, varscan2
- UQCRFS1 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1309796054, COSV100508253; called by muse, mutect2
- USH2A | c.8845+2T>A p.X2949_splice | Splice Site (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100244044; called by muse, mutect2
- USP15 | c.1229C>T p.A410V (on ENST00000280377 / NM_001351159.2; = p.A381V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99740958; called by muse, mutect2, varscan2
- VCAN | c.3084G>T p.E1028D | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV99427557; called by muse, mutect2, varscan2
- VCAN | c.3085G>T p.G1029* | Nonsense Mutation (SNP) | VAF 17/21 reads (81%) | catalogued as COSV99427745; called by muse, mutect2, varscan2
- VSIR | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs375739009; called by muse, mutect2, varscan2
- WDR3 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100832426; called by muse, mutect2, varscan2
- WDR70 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV99460867; called by muse, varscan2
- WNK4 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99519602; called by muse, mutect2, varscan2
- ZAN | c.240del p.Y81Tfs*96 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | catalogued as rs773398085, COSV61809202; called by mutect2, pindel
- ZBBX | c.528+1G>T p.X176_splice | Splice Site (SNP) | VAF 268/387 reads (69%) | catalogued as rs1483857646, COSV56789625, COSV56794118; called by muse, mutect2, varscan2
- ZC3H14 | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99193324; called by muse, mutect2, varscan2
- ZNF100 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as COSV100841454; called by muse, mutect2, varscan2
- ZNF283 | c.357T>A p.Y119* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100191140; called by muse, mutect2
- ZNF761 | c.1419A>T p.K473N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100483525; called by muse, mutect2, varscan2
- ZNF835 | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV101606420; called by muse, mutect2
- AATF | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COPG2 | c.2458A>C p.K820Q | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2
- F8 | c.3157_3158del p.E1053Kfs*2 | Frame Shift Del (DEL) | VAF 26/46 reads (57%) | called by mutect2, pindel, varscan2
- HSD17B14 | c.108_111del p.V37Sfs*26 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.748G>C p.D250H (on ENST00000396284; = p.D211H on NM_001080770.2) | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, varscan2
- NR2C2AP | c.391dup p.H131Pfs*54 | Frame Shift Ins (INS) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- OR7G2 | c.846_847del p.S283Cfs*4 | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by mutect2, pindel*, varscan2*
- PCF11 | c.828dup p.E277* | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- PTH2R | c.981+1dup | Frame Shift Ins (INS) | VAF 16/154 reads (10%) | called by mutect2, pindel
- PTPRE | c.2080dup p.S694Ffs*2 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- RBP3 | c.2861C>A p.S954Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPATA31A1 | c.3691A>T p.K1231* | Nonsense Mutation (SNP) | VAF 196/297 reads (66%) | called by muse, mutect2, varscan2
- SSRP1 | c.633_634delinsA p.G212Vfs*45 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by pindel, varscan2*
- TMEM164 | c.5_16del p.S2_S5del | In Frame Del (DEL) | VAF 54/87 reads (62%) | called by mutect2, pindel, varscan2
- AICDA | c.300G>T p.G100= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV57566402, COSV99984418; called by muse, mutect2, varscan2
- CD79B | c.309T>C p.S103= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99138031; called by muse, mutect2, varscan2
- CTSE | c.285C>T p.F95= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs375185846; called by muse, mutect2
- DUOX2 | c.2784G>T p.L928= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101199926; called by muse, mutect2, varscan2
- DYNC2LI1 | c.306A>T p.T102= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV53183869, COSV99571668; called by muse, mutect2, varscan2
- ELFN2 | c.879G>T p.A293= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV101297668, COSV68746015; called by muse, mutect2
- ETV4 | c.1344C>T p.V448= | Silent (SNP) | VAF 74/134 reads (55%) | catalogued as COSV99292732; called by muse, mutect2, varscan2
- EXOC3L2 | c.1599C>T p.R533= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs571153044, COSV99374672; called by muse, mutect2, varscan2
- FAT4 | c.6672C>T p.T2224= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100630562; called by muse, mutect2, varscan2
- FREM2 | c.759G>T p.L253= | Silent (SNP) | VAF 56/85 reads (66%) | catalogued as COSV99751497; called by muse, mutect2, varscan2
- GABRB3 | c.960C>A p.A320= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100162431; called by muse, mutect2
- GALNT9 | c.1362G>A p.P454= (on ENST00000328957 / NM_001122636.2; = p.P88= on NM_021808.3) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs377144604; called by muse, mutect2, varscan2
- GFRA1 | c.174C>A p.T58= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100816304; called by muse, mutect2, varscan2
- GPR158 | c.2493C>G p.S831= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV100894420, COSV66269487; called by muse, mutect2, varscan2
- GTF3C1 | c.2073G>A p.V691= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100649813; called by muse, mutect2, varscan2
- HBD | c.330G>A p.V110= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs770433973, COSV99496923; called by muse, mutect2, varscan2
- HES1 | c.432C>G p.A144= | Silent (SNP) | VAF 15/264 reads (6%) | catalogued as COSV99220647; called by muse, mutect2
- HPS5 | c.370C>A p.R124= (on ENST00000349215 / NM_181507.2; = p.R10= on NM_007216.4) | Silent (SNP) | VAF 42/54 reads (78%) | catalogued as COSV100834486, COSV62539143; called by muse, mutect2, varscan2
- ICAM1 | c.51C>T p.L17= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53425274; called by muse, mutect2, varscan2
- JAK1 | c.2346G>A p.T782= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs537477751, COSV61097007; called by muse, mutect2, varscan2
- KRT6B | c.1056T>A p.A352= | Silent (SNP) | VAF 79/300 reads (26%) | catalogued as COSV99361097; called by muse, mutect2, varscan2
- LRRC6 | c.501A>T p.P167= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV99138798; called by muse, mutect2, varscan2
- MAGEA8 | c.396G>T p.P132= | Silent (SNP) | VAF 71/87 reads (82%) | catalogued as COSV99674867; called by muse, mutect2, varscan2
- MAST1 | c.126T>A p.T42= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV99263864; called by muse, mutect2, varscan2
- MEDAG | c.741C>A p.I247= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as COSV100995338, COSV66849860; called by muse, mutect2, varscan2
- MKI67 | c.423G>A p.K141= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100897091; called by muse, mutect2, varscan2
- MME | c.1527G>A p.E509= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV100852577; called by muse, mutect2, varscan2
- MRPL2 | c.741A>G p.V247= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99539411; called by muse, mutect2
- MS4A14 | c.1044T>A p.S348= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100280785; called by muse, mutect2, varscan2
- NKX2-2 | c.138G>T p.G46= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV101010643; called by muse, mutect2, varscan2
- NPHS1 | c.3174G>A p.S1058= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1329741277, COSV100800350; called by muse, mutect2
- ONECUT1 | c.1269G>T p.G423= | Silent (SNP) | VAF 62/149 reads (42%) | catalogued as rs749522422, COSV100009503, COSV59947679; called by muse, mutect2, varscan2
- OR2G2 | c.183G>T p.P61= | Silent (SNP) | VAF 66/185 reads (36%) | catalogued as rs1177469166, COSV100190063, COSV60740277; called by muse, mutect2, varscan2
- OR4M1 | c.669C>A p.A223= | Silent (SNP) | VAF 130/182 reads (71%) | catalogued as rs1222859124, COSV100271318; called by muse, mutect2, varscan2
- PCOLCE2 | c.915G>A p.G305= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as rs1490629042, COSV99930996; called by muse, mutect2, varscan2
- PIK3CB | c.2928A>T p.T976= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV100006222; called by muse, mutect2, varscan2
- PLCB1 | c.1060C>T p.L354= | Silent (SNP) | VAF 69/206 reads (33%) | catalogued as rs563074402, COSV100569432; called by muse, mutect2, varscan2
- POLR3K | c.132A>G p.P44= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99550463; called by muse, mutect2, varscan2
- PPFIA4 | c.930T>A p.R310= | Silent (SNP) | VAF 84/237 reads (35%) | catalogued as COSV99830634; called by muse, mutect2, varscan2
- RIMS2 | c.1791A>T p.S597= (on ENST00000666250 / NM_001348490.2; = p.S405= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV99212476; called by muse, mutect2, varscan2
- RPS13 | c.159C>A p.I53= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV99930623; called by muse, mutect2, varscan2
- SCN5A | c.60C>A p.S20= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV100028544, COSV60068139; called by muse, mutect2, varscan2
- SLC44A2 | c.918G>T p.R306= | Silent (SNP) | VAF 96/180 reads (53%) | catalogued as COSV100213525; called by muse, mutect2, varscan2
- SLITRK2 | c.1482G>T p.T494= | Silent (SNP) | VAF 109/145 reads (75%) | catalogued as COSV100158329; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3448C>A p.R1150= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV100562367; called by muse, mutect2, varscan2
- TARBP1 | c.2061G>A p.K687= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV99242226; called by muse, mutect2, varscan2
- TAS2R19 | c.861A>G p.K287= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs748879465, COSV101115892; called by muse, mutect2, varscan2
- TMEM183A | c.687C>A p.P229= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as COSV100923871; called by muse, mutect2
- TRDN | c.777A>G p.S259= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as COSV100523654; called by muse, mutect2, varscan2
- TTC14 | c.1935G>A p.R645= | Silent (SNP) | VAF 144/201 reads (72%) | catalogued as COSV99870946; called by muse, mutect2, varscan2
- TTN | c.65940C>A p.P21980= (on ENST00000591111; = p.P14556= on NM_003319.4) | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV100634908; called by muse, mutect2, varscan2
- UHRF1BP1 | c.378C>T p.F126= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV99512599; called by muse, mutect2, varscan2
- VPS11 | c.624A>G p.P208= (on ENST00000620429; = p.P752= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV100334048; called by muse, mutect2, varscan2
- WEE1 | c.1113T>C p.H371= | Silent (SNP) | VAF 69/93 reads (74%) | catalogued as COSV100219857; called by muse, mutect2, varscan2
- ZCCHC12 | c.414A>G p.L138= | Silent (SNP) | VAF 144/178 reads (81%) | catalogued as rs369981600, COSV100038711; called by muse, mutect2, varscan2
- ZNF100 | c.507G>A p.L169= | Silent (SNP) | VAF 25/210 reads (12%) | catalogued as COSV99974418; called by muse, mutect2, varscan2
- ZNF283 | c.270G>T p.L90= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100161477; called by muse, mutect2, varscan2
- AGAP7P | n.811G>A | RNA (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- C3P1 | n.2358A>G | RNA (SNP) | VAF 26/952 reads (3%) | called by muse, mutect2
- HNF4G | c.-23-3794G>C | Intron (SNP) | VAF 43/182 reads (24%) | catalogued as COSV100585137; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23167168 del G | 3'Flank (DEL) | VAF 24/30 reads (80%) | called by mutect2, varscan2
- SAPCD1 | c.352-109del | Intron (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- TUBB7P | n.968T>G | RNA (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- UBTFL2 | n.604A>G | RNA (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
